Somatic mutation profile of cancer-model specimen HCM-CSHL-0193-C25-85A (3D Organoid; aliquot HCM-CSHL-0193-C25-85A-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0193-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 46.9 years (17,138 days).
Specimen HCM-CSHL-0193-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 709ad569-d7f9-4bef-a9f2-0205fb6ee9c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0193-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0193-C25-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68706607-fdc6-496a-b277-26dda9dfb3b7

The open-access MAF lists 61 somatic variants for this specimen: 47 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 12, Nonsense Mutation 3, Intron 2, Frame Shift Ins 2, Frame Shift Del 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 151/348 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 306/610 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397516792, CM071852, CM073191, COSV61068422, COSV61068985, COSV61070219; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.745A>T p.R249W | Missense Mutation (SNP) | VAF 183/183 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs587782082, COSV52662247, COSV52676356, COSV52892337, COSV52908430; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADRA2B | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 111/235 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV101337393; called by muse, mutect2, varscan2
- BCL9L | c.2482G>A p.V828M | Missense Mutation (SNP) | VAF 184/430 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747103686, COSV52681724; called by muse, mutect2, varscan2
- CDH18 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 95/212 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.401); catalogued as rs148450624, COSV56937399; called by muse, mutect2, varscan2
- ENO2 | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 142/311 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs781911082; called by muse, mutect2, varscan2
- FBXL7 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 108/215 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as rs754526877, COSV61641324; called by muse, mutect2, varscan2
- GAK | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs749984140, COSV58509672; called by muse, mutect2, varscan2
- KDM6A | c.3763C>T p.R1255W | Missense Mutation (SNP) | VAF 175/176 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1450363794, COSV65037148; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KMT2D | c.7604G>A p.R2535H | Missense Mutation (SNP) | VAF 101/196 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs756461524; called by muse, mutect2, varscan2
- LRFN2 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 40/40 reads (100%) | SIFT tolerated (0.55); PolyPhen benign (0.074); catalogued as rs767471179, COSV57827020; called by muse, mutect2, varscan2
- METTL17 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 33/284 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775852895, COSV53870526; called by muse, mutect2
- MPP2 | c.1214C>T p.T405M (on ENST00000461854 / NM_001278372.2; = p.T381M on NM_005374.5) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV104393489; called by muse, mutect2, varscan2
- MTOR | c.4451T>C p.L1484P | Missense Mutation (SNP) | VAF 67/132 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV63875792; called by muse, mutect2, varscan2
- MUC19 | n.5746G>A | Splice Region (SNP) | VAF 73/177 reads (41%) | catalogued as rs577962513; called by muse, mutect2, varscan2
- NT5C1B | c.241C>G p.R81G | Missense Mutation (SNP) | VAF 121/291 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV100409913; called by muse, mutect2, varscan2
- PCSK4 | c.507G>A p.W169* | Nonsense Mutation (SNP) | VAF 53/116 reads (46%) | catalogued as rs142821760; called by muse, mutect2, varscan2
- PTGES2 | c.646_648del p.K216del | In Frame Del (DEL) | VAF 58/123 reads (47%) | catalogued as rs775108932; called by mutect2, pindel, varscan2
- SALL1 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 302/623 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1273770690, COSV51755316; called by muse, varscan2
- SERPINA10 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 220/478 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs143859072; called by muse, mutect2, varscan2
- SGIP1 | c.560G>T p.S187I | Missense Mutation (SNP) | VAF 31/399 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV99390641; called by muse, mutect2
- SLC30A3 | c.1159dup p.Q387Pfs*27 | Frame Shift Ins (INS) | VAF 78/200 reads (39%) | catalogued as rs747206800; called by mutect2, varscan2
- SRBD1 | c.376A>G p.T126A | Missense Mutation (SNP) | VAF 237/524 reads (45%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs752317761, COSV55397521; called by muse, mutect2, varscan2
- SSC5D | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as rs748737671, COSV52698110; called by muse, mutect2, varscan2
- SYNPO2 | c.1079G>A p.R360K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61115952; called by muse, mutect2
- TENM2 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 223/429 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs773543508, COSV72859296; called by muse, mutect2, varscan2
- TGFBR2 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 282/282 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as rs397516839; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TKTL2 | c.171G>T p.M57I | Missense Mutation (SNP) | VAF 88/88 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54918042; called by muse, mutect2, varscan2
- TRIM64B | c.1260dup p.D421* | Frame Shift Ins (INS) | VAF 132/540 reads (24%) | catalogued as rs748440706; called by mutect2, varscan2
- TSHZ2 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs367984099; called by muse, mutect2, varscan2
- TULP2 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 72/142 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs117499417, COSV55479089; called by muse, mutect2, varscan2
- ARRDC5 | c.428A>C p.H143P (on ENST00000381781; = p.H129P on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 160/358 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CDH15 | c.1930del p.Q644Rfs*35 | Frame Shift Del (DEL) | VAF 98/209 reads (47%) | called by mutect2, varscan2
- CFAP92 | c.686T>A p.L229* | Nonsense Mutation (SNP) | VAF 86/204 reads (42%) | called by muse, mutect2, varscan2
- CUBN | c.10038C>A p.H3346Q | Missense Mutation (SNP) | VAF 116/237 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- DCAF8L1 | c.1309A>G p.N437D | Missense Mutation (SNP) | VAF 90/91 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- DICER1 | c.2926del p.Y976Tfs*5 | Frame Shift Del (DEL) | VAF 161/405 reads (40%) | called by mutect2, pindel, varscan2
- HAT1 | c.883C>A p.Q295K | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT tolerated (0.92); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- JPH1 | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 174/387 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LCE1D | c.35C>A p.P12H | Missense Mutation (SNP) | VAF 212/215 reads (99%) | PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LCMT1 | c.269G>T p.C90F | Missense Mutation (SNP) | VAF 51/271 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- PRUNE2 | c.6101A>C p.E2034A | Missense Mutation (SNP) | VAF 144/296 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- REXO1 | c.3133G>A p.V1045M | Missense Mutation (SNP) | VAF 171/378 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- SPEG | c.1579C>A p.P527T | Missense Mutation (SNP) | VAF 157/323 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- SPIRE2 | c.1609A>G p.T537A | Missense Mutation (SNP) | VAF 167/360 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIM49C | c.448A>T p.K150* | Nonsense Mutation (SNP) | VAF 32/254 reads (13%) | called by muse, mutect2, varscan2
- CLEC4M | c.1131C>T p.N377= | Silent (SNP) | VAF 78/199 reads (39%) | catalogued as rs753400349; called by muse, mutect2, varscan2
- COQ2 | c.15A>T p.S5= | Silent (SNP) | VAF 125/403 reads (31%) | called by muse, mutect2, varscan2
- DHX8 | c.400T>C p.L134= | Silent (SNP) | VAF 122/233 reads (52%) | called by muse, mutect2, varscan2
- GRM8 | c.702C>T p.A234= | Silent (SNP) | VAF 13/334 reads (4%) | called by muse, mutect2
- ITGAM | c.771G>A p.T257= | Silent (SNP) | VAF 115/266 reads (43%) | catalogued as rs761611533, COSV54935794; called by muse, mutect2, varscan2
- MYO1G | c.1290G>A p.Q430= | Silent (SNP) | VAF 24/299 reads (8%) | called by muse, mutect2
- NRXN3 | c.1797G>A p.T599= (on ENST00000557594 / NM_001272020.2; = p.T1023= on NM_004796.6) | Silent (SNP) | VAF 127/276 reads (46%) | catalogued as rs773510809, COSV99814775; called by muse, mutect2, varscan2
- NUP98 | c.4689G>A p.E1563= (on ENST00000359171 / NM_001365126.1; = p.E1546= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 149/281 reads (53%) | called by muse, mutect2, varscan2
- OR10R2 | c.477G>A p.Q159= | Silent (SNP) | VAF 89/190 reads (47%) | catalogued as rs1249773388, COSV100936752; called by muse, mutect2, varscan2
- PAQR4 | c.789C>T p.L263= | Silent (SNP) | VAF 58/110 reads (53%) | called by muse, mutect2, varscan2
- SLITRK1 | c.363T>C p.F121= | Silent (SNP) | VAF 22/240 reads (9%) | called by muse, mutect2
- TMCO3 | c.349C>T p.L117= | Silent (SNP) | VAF 154/154 reads (100%) | catalogued as COSV100952219; called by muse, mutect2, varscan2
- LIN7A | c.82+1847T>A | Intron (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- OBSCN | c.18662-2932G>A | Intron (SNP) | VAF 35/76 reads (46%) | catalogued as rs546316599, COSV99476659; called by muse, mutect2, varscan2
